CCDI case PBCLKS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/1c197a63-97ae-4003-8d73-2b9e851f455e

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Retinoblastoma, NOS: ICD-O-3 morphology code: 9510/3; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 0.9 years (342 days).

Biospecimens (3 samples)
- Sample 0DV7GQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DV7GU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV7GX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
